Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A7IP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A7IP-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology [OrderID:]	Final Results
Surgical Pathology	Final
CASE NUMBER:	
DIAGNOSIS: Mass, para-aortic, resection: Paraganglioma, extra-adrenal.	
NOTE:	
Specimen	
Para-aortic mass: Fresh	
Procedure	
Excision	
Specimen Integrity	
Intact	
Specimen Size	
Greatest dimensions: 2.4 x 2.2 x 0.9 cm	
Specimen Laterality	
Other: Para-aortic	
Tumor Size	
Greatest dimension: 2.4 cm	
Tumor Description	
Invasion: Indeterminate given that the tumor capsule is incomplete and cannot be completely evaluated	
Histologic Type	
Paraganglioma	
Margins	
Margin(s) involved by tumor: Tumor extends to the black-inked margin	
Lymph-Vascular Invasion	
Indeterminate	
Perineural Invasion	
Not identified	
Lymph Nodes, Extranodal Extension	
Not identified	
Pathologic Staging (pTNM)	
Primary Tumor (pT)	
pT1: Tumor 5 cm or less in greatest dimension, no extra-adrenal invasion	
Regional Lymph Nodes (pN)	
No nodes submitted or found	
Distant Metastasis (pM)	
Not applicable	

ICD-O-3
Paraganglioma, extra adrenal
8693/1
Site: Retroperitoneum
C48.0
J20117/14

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

[page 2 of 3]
Clinical History

Other (specify): SDHB mutation

Comment: Probable capsular lymphovascular invasion is present, but difficult to define with full certainty due to the limited extratumoral material in the specimen.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the _____. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: Paraganglioma - SDHB mutation.

Specimen Taken For Protocol: 01 - Yes.

Allocate Order to Protocol:

PROCEDURE: Pre-Operative Diagnosis: Paraganglioma.

Post-Operative Diagnosis: Same.

Operative Findings: Paraganglioma.

SPECIMENS SUBMITTED: 1. TUMOR, Para aortic mass

GROSS DESCRIPTION: Received fresh from the OR in a container labeled with the patient's name, medical record number, and "para-aortic mass" is a soft red-tan tissue mass measuring 2.4 x 2.2 x 0.9 cm. The cut surface is variegated and red-tan in color. Gross photographs are taken. Approximately 50% of the tissue is procured for

The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. The procurement was performed by _____ on _____. Received in Surgical Pathology is a specimen matching the above description. The nodule measures 2.3 cm in length and 1.5 cm in width and the external surface of it has been inked in black. The cut surface is tan-brown and there is a small focus of yellow granular nodularity measuring 1.0 x 0.8 cm. The specimen is serially sectioned and entirely submitted in cassettes labeled _____ A-D.

Gross Description dictated by _____

Accessioned: _____

Final Report Signed Out: _____

<Resident Signature> _____

[page 3 of 3]
Surgical Pathology [OrderID: _____]

Final Results

<Sign Out Dr. Signature>

Date Report Signed:

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

Source: NCI Genomic Data Commons file f1a6c7ec-db78-4c82-8068-a2348b132069 (TCGA-QR-A7IP.A6D20E77-B8D9-4D20-B920-1E55143A5D8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).